Somatic mutation profile of tumor specimen C3L-07093-02 (aliquot CPT0431870006) from CPTAC case C3L-07093, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 55.9 years (20,425 days).
Specimen C3L-07093-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5b67f3-fa22-4276-b9a8-5509e59bd09b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07093-32 (Blood Derived Normal), aliquot CPT0432010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db21b70e-7014-4bb9-bebf-72962a98a918

The open-access MAF lists 1,250 somatic variants for this specimen: 923 protein-altering or splice-affecting, 272 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 643, Silent 272, Frame Shift Del 177, Frame Shift Ins 54, Intron 27, Nonsense Mutation 27, 3'UTR 16, In Frame Del 12, Splice Region 6, RNA 3, 3'Flank 3, Splice Site 3.

Variants (750 of 1,250; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 97/584 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1057518686, COSV100206122; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 44/358 reads (12%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 56/372 reads (15%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 36/290 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MEN1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 73/443 reads (16%) | catalogued as rs1060499974, CD148208, CD982775, CM970937, COSV53641032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 80/260 reads (31%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 38/243 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 39/261 reads (15%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC24A5 | c.1361dup p.L454Ffs*33 | Frame Shift Ins (INS) | VAF 32/220 reads (15%) | catalogued as rs886037644; ClinVar: pathogenic; called by mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 41/285 reads (14%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.4334C>A p.A1445E | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200447138; called by muse, mutect2, varscan2
- AACS | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.107); catalogued as rs549236885; called by muse, mutect2, varscan2
- ABCA13 | c.12799G>A p.E4267K | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101291485, COSV68946127; called by muse, mutect2, varscan2
- ABCA5 | c.2930T>C p.V977A | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1295674293, COSV67019119; called by muse, mutect2
- ABL1 | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 94/571 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.572); catalogued as COSV59333716; called by muse, mutect2, varscan2
- AC092143.1 | c.1463del p.G488Afs*24 | Frame Shift Del (DEL) | VAF 39/312 reads (13%) | catalogued as rs752133648; called by mutect2, pindel, varscan2
- AC092143.1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 66/528 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs587784506, COSV59247047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC138647.1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 78/660 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); catalogued as COSV70194539; called by muse, mutect2, varscan2
- ACTB | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV59316650; called by muse, mutect2, varscan2
- ACTN2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.833); catalogued as rs758358941, COSV63973008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 38/199 reads (19%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM30 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs1325470850, COSV65562370; called by muse, mutect2, varscan2
- ADAMTSL4 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 80/507 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs771998925, COSV54996732; called by muse, mutect2, varscan2
- ADCY6 | c.2897G>A p.R966H | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs760633041; called by muse, mutect2, varscan2
- ADGRB1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 187/854 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as rs993452326; called by muse, mutect2, varscan2
- ADGRB1 | c.2696del p.P899Rfs*34 | Frame Shift Del (DEL) | VAF 49/228 reads (21%) | catalogued as rs1554616325; called by mutect2, pindel, varscan2
- ADGRG4 | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755748491; called by muse, mutect2, varscan2
- ADRA2A | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs867426803, COSV54529302; called by muse, varscan2
- AKAP12 | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 71/479 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142292034; called by muse, mutect2, varscan2
- AL136295.1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 95/523 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759491065, COSV55778221; called by muse, mutect2, varscan2
- ANK2 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138381417; called by muse, mutect2, varscan2
- ANKRD34A | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 106/561 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60160584; called by muse, mutect2, varscan2
- ANKS3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1234787138, COSV58508612; called by muse, mutect2, varscan2
- ANTXR1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.328); catalogued as rs376960445; called by muse, mutect2, varscan2
- ANXA8L1 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1345781844; called by muse, mutect2, varscan2
- AP002748.5 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 82/560 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs200297847; called by muse, mutect2, varscan2
- AP1B1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1207787639, COSV58014462; called by muse, mutect2, varscan2
- AP2A2 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs752237271, COSV100172535; called by muse, mutect2, varscan2
- APCDD1L | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 86/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1243991394; called by muse, mutect2, varscan2
- APMAP | c.538+1G>A p.X180_splice | Splice Site (SNP) | VAF 37/236 reads (16%) | catalogued as rs1440409052; called by muse, mutect2, varscan2
- APOB | c.4928C>T p.A1643V | Missense Mutation (SNP) | VAF 63/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1008238083, COSV51931582; called by muse, mutect2, varscan2
- AQP2 | c.332A>C p.D111A | Missense Mutation (SNP) | VAF 73/509 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99550969; called by muse, mutect2, varscan2
- ARHGAP1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100358031; called by muse, mutect2, varscan2
- ARHGAP39 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 75/625 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1218993898; called by muse, mutect2, varscan2
- ARHGEF17 | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs779817536, COSV55229264; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 68/455 reads (15%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMCX3 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 73/476 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs372051555, COSV57871198; called by muse, mutect2, varscan2
- ASB14 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 89/445 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs767635090; called by muse, mutect2, varscan2
- ATAD2 | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1169009482; called by muse, mutect2, varscan2
- ATF6 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148863991; called by muse, mutect2, varscan2
- ATL1 | c.458G>A p.S153N | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as CM1213392; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774595060; called by muse, varscan2
- ATP8A1 | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs754952867, COSV52537746; called by muse, mutect2, varscan2
- B3GALNT2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs111541487, COSV64003600; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAIAP2L2 | c.799dup p.R267Pfs*166 | Frame Shift Ins (INS) | VAF 43/294 reads (15%) | catalogued as rs768717523; called by mutect2, pindel, varscan2
- BANK1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1337372347; called by muse, mutect2, varscan2
- BCL11B | c.2194G>A p.A732T (on ENST00000357195 / NM_001282237.2; = p.A661T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/551 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV61738467; called by muse, mutect2, varscan2
- BCL9L | c.2695_2697del p.P899del | In Frame Del (DEL) | VAF 75/529 reads (14%) | catalogued as rs773238036; called by pindel, varscan2
- BCORL1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 94/770 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.573); catalogued as rs143414966, COSV54399360; called by muse, mutect2, varscan2
- BDP1 | c.4309C>T p.R1437* | Nonsense Mutation (SNP) | VAF 55/394 reads (14%) | catalogued as rs777807458; called by muse, mutect2, varscan2
- BLZF1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as rs755067884; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 34/295 reads (12%) | catalogued as rs751941533; called by pindel, varscan2
- BOD1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.823); catalogued as rs371715563; called by muse, mutect2
- BRINP1 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 53/441 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99774317; called by muse, mutect2, varscan2
- C1QTNF5 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 77/582 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.093); catalogued as COSV60990948; called by muse, mutect2, varscan2
- C2orf16 | c.5725C>T p.R1909C | Missense Mutation (SNP) | VAF 69/499 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs762030907, COSV62677594; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 35/282 reads (12%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C3orf80 | c.374del p.G125Afs*61 | Frame Shift Del (DEL) | VAF 66/523 reads (13%) | catalogued as rs775962517; called by mutect2, pindel, varscan2
- C6orf118 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.887); catalogued as rs201539458, COSV57815326; called by muse, mutect2, varscan2
- CACNA1I | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 58/266 reads (22%) | catalogued as COSV60810360; called by muse, mutect2, varscan2
- CACNB3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs759601414, COSV99975047; called by muse, mutect2, varscan2
- CACNG8 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 82/593 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.162); catalogued as rs770734902, COSV99555019; called by muse, mutect2, varscan2
- CALD1 | c.1585del p.Q529Rfs*76 (on ENST00000361675 / NM_033138.4; = p.Q274Rfs*76 on NM_004342.7) | Frame Shift Del (DEL) | VAF 72/518 reads (14%) | catalogued as rs1554474721; called by mutect2, pindel, varscan2
- CALML3 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 82/572 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1293005650; called by muse, mutect2, varscan2
- CASP8 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99966296; called by muse, mutect2, varscan2
- CATIP | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs963456968, COSV56824413; called by muse, mutect2, varscan2
- CC2D2B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 55/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373755580; called by muse, mutect2, varscan2
- CCDC113 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 34/251 reads (14%) | catalogued as rs369793227; called by muse, mutect2, varscan2
- CCDC18 | c.3856G>A p.A1286T (on ENST00000343253 / NM_001306076.1; = p.A1287T on NM_206886.4) | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs376862951; called by muse, mutect2, varscan2
- CCDC3 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 106/537 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as rs11545579, COSV66561678; called by muse, mutect2, varscan2
- CCDC88A | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs748202371, COSV55063871; called by muse, mutect2, varscan2
- CCIN | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs780732608; called by muse, mutect2, varscan2
- CCN1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs146738107; called by muse, mutect2, varscan2
- CCNI2 | c.133del p.E45Rfs*138 | Frame Shift Del (DEL) | VAF 63/534 reads (12%) | catalogued as rs1451822015; called by mutect2, varscan2
- CDH10 | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 69/476 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52601162; called by muse, mutect2, varscan2
- CDH6 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs765207601; called by muse, mutect2, varscan2
- CDH6 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV54065519; called by muse, mutect2, varscan2
- CEP104 | c.7dup p.H3Pfs*36 | Frame Shift Ins (INS) | VAF 52/332 reads (16%) | catalogued as rs751259031; called by mutect2, pindel, varscan2
- CEP128 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs747660649, COSV53672366; called by muse, mutect2, varscan2
- CEP131 | c.2977C>T p.R993C (on ENST00000269392 / NM_001319228.2; = p.R990C on NM_014984.4) | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1253050642, COSV53953858; called by muse, varscan2
- CEP170B | c.1043G>A p.R348H (on ENST00000453495; = p.R277H on NM_015005.3) | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768650007, COSV69025321; called by muse, mutect2, varscan2
- CEP85 | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.346); catalogued as rs780700758; called by muse, mutect2, varscan2
- CFAP61 | c.2121del p.K707Nfs*11 | Frame Shift Del (DEL) | VAF 39/316 reads (12%) | catalogued as rs1220155674; called by mutect2, pindel, varscan2
- CHD3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 68/409 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57875152; called by muse, mutect2, varscan2
- CHRM4 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 96/526 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1033644783; called by muse, mutect2, varscan2
- CILP2 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 110/721 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568875862; called by muse, mutect2, varscan2
- CLDN16 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 72/481 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758946923, CM034403, CP015768, COSV53229765; called by muse, mutect2, varscan2
- CLEC16A | c.3098C>G p.A1033G | Missense Mutation (SNP) | VAF 104/645 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV55488665, COSV55488767; called by muse, mutect2, varscan2
- CLTCL1 | c.2720G>A p.R907H | Missense Mutation (SNP) | VAF 52/435 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1214337596; called by muse, mutect2, varscan2
- CMSS1 | c.156T>C p.P52= | Splice Region (SNP) | VAF 24/175 reads (14%) | catalogued as rs1481987617; called by muse, mutect2, varscan2
- CMTM7 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.304); catalogued as rs1017441804, COSV58550925; called by muse, mutect2, varscan2
- CNOT10 | c.1574A>G p.K525R | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs373537442; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 48/324 reads (15%) | catalogued as rs748995811; called by mutect2, varscan2
- COL22A1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs770249679, COSV100279616; called by muse, mutect2, varscan2
- COL6A2 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 65/489 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs148552966; ClinVar: uncertain significance; called by muse, varscan2
- CPNE5 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 79/586 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs375106654; called by muse, mutect2, varscan2
- CPT1C | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779171628; called by muse, mutect2, varscan2
- CSF2RA | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 77/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393687642; called by muse, mutect2, varscan2
- CSMD2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as rs200640948, COSV99592858; called by muse, mutect2, varscan2
- CSMD3 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 46/379 reads (12%) | catalogued as COSV52092294; called by muse, mutect2, varscan2
- CSNKA2IP | c.1805del p.N602Ifs*58 | Frame Shift Del (DEL) | VAF 66/397 reads (17%) | catalogued as rs553580070; called by mutect2, varscan2
- CTBP2 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs1424208268; called by muse, mutect2, varscan2
- CTCF | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs779672689, COSV50532120; called by muse, mutect2, varscan2
- CTSF | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs563045234; called by muse, mutect2
- CTSK | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV55011554, COSV55012182; called by muse, mutect2, varscan2
- CUL1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as rs369272126, COSV57393434; called by muse, mutect2
- CUL7 | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs1313068084; called by muse, mutect2, varscan2
- CXCR5 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 77/555 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1346203529; called by muse, mutect2, varscan2
- DAPK1 | c.3596G>A p.R1199H | Missense Mutation (SNP) | VAF 85/486 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs953877229; called by muse, mutect2, varscan2
- DAZAP1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1191774075; called by muse, varscan2
- DBX1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 71/489 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99910357; called by muse, mutect2, varscan2
- DCHS2 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 97/560 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.047); catalogued as rs1320033770, COSV59733185; called by muse, mutect2, varscan2
- DEDD | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 74/487 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs150690350; called by muse, mutect2, varscan2
- DENND1A | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs1465850668, COSV101011734, COSV101011954; called by muse, mutect2, varscan2
- DENND2B | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375990683; called by muse, mutect2, varscan2
- DHDDS | c.874G>A p.A292T (on ENST00000236342 / NM_001319959.1; = p.A293T on NM_024887.3) | Missense Mutation (SNP) | VAF 59/515 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs376234168; called by muse, mutect2, varscan2
- DHX58 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs782664534, COSV52428263; called by muse, mutect2
- DIP2C | c.4412C>T p.T1471M | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1234520782, COSV55174261; called by muse, mutect2, varscan2
- DLGAP3 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs746903257; called by muse, mutect2, varscan2
- DNAH10 | c.8578G>A p.A2860T (on ENST00000409039; = p.A2799T on NM_207437.3) | Missense Mutation (SNP) | VAF 79/526 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs751930117; called by muse, mutect2, varscan2
- DNAH8 | c.4559G>A p.R1520H | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs568480936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 49/262 reads (19%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP7 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs780798520; called by muse, mutect2, varscan2
- DSG2 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 56/405 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV99853041; called by muse, mutect2, varscan2
- DUSP8 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 106/716 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs767368858; called by muse, mutect2, varscan2
- ECPAS | c.5093C>T p.P1698L | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774395059, COSV52196678; called by muse, mutect2, varscan2
- EFHC2 | c.1314dup p.A439Cfs*10 | Frame Shift Ins (INS) | VAF 39/285 reads (14%) | catalogued as rs752671785; called by mutect2, varscan2
- EIF2S3B | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 64/432 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.935); catalogued as rs761401996, COSV100483577; called by muse, mutect2, varscan2
- ELMO1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs146510671; called by muse, mutect2, varscan2
- ENOX2 | c.655C>T p.R219C (on ENST00000338144 / NM_001382520.1; = p.R190C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/536 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762779115, COSV57648899; called by muse, mutect2, varscan2
- EPHA5 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56643710, COSV99897943; called by muse, mutect2, varscan2
- ERC2 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 59/421 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs563601997, COSV99891316; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 56/438 reads (13%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 51/336 reads (15%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EXO1 | c.1515G>T p.R505S | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs1024525498, COSV62219274; called by muse, mutect2, varscan2
- FAH | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as CD119761; called by muse, mutect2, varscan2
- FAM124A | c.230C>T p.P77L (on ENST00000322475 / NM_001242312.2; = p.P113L on NM_145019.4) | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs375404288; called by muse, mutect2, varscan2
- FAM167A | c.234dup p.Q79Afs*40 | Frame Shift Ins (INS) | VAF 70/548 reads (13%) | catalogued as rs1252762581; called by mutect2, pindel, varscan2
- FAM187B | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61201785; called by muse, mutect2, varscan2
- FAM216A | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.099); catalogued as rs139016905; called by muse, mutect2, varscan2
- FAM43B | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs767152826; called by muse, mutect2, varscan2
- FAM83G | c.1489del p.D497Tfs*20 | Frame Shift Del (DEL) | VAF 54/517 reads (10%) | catalogued as COSV58760026; called by mutect2, pindel, varscan2
- FAXC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1485482567, COSV101067170, COSV67602636; called by muse, mutect2, varscan2
- FBL | c.681C>T p.I227= | Splice Region (SNP) | VAF 47/287 reads (16%) | catalogued as rs369924506; called by muse, mutect2, varscan2
- FBLN1 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs540607391, COSV53045235; called by muse, mutect2, varscan2
- FBLN2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 93/564 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs758652354, COSV55480510, COSV55487370; called by muse, mutect2, varscan2
- FBN3 | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs143230386, COSV54465166, COSV99561951; called by muse, mutect2, varscan2
- FERMT3 | c.1930C>T p.R644W (on ENST00000279227 / NM_178443.3; = p.R640W on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886043481, COSV54174076, COSV54176018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 83/497 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1162044129, COSV100910761; called by muse, mutect2, varscan2
- FGF3 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 98/570 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1554981421, COSV61926439; called by muse, mutect2, varscan2
- FHL1 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 90/600 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs367592190; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 54/398 reads (14%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FLRT2 | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 70/440 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV58148752; called by muse, mutect2, varscan2
- FOXD4L5 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 82/1307 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs752080978, COSV101073288; called by muse, mutect2
- FPR3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 80/445 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs771806602, COSV59328411; called by muse, mutect2, varscan2
- FREM2 | c.5581del p.V1861Cfs*50 | Frame Shift Del (DEL) | VAF 50/422 reads (12%) | catalogued as COSV54854389, COSV54855129; called by mutect2, pindel, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 70/478 reads (15%) | catalogued as rs752538869; called by mutect2, varscan2
- FSD1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs770312605; called by muse, varscan2
- FUBP1 | c.483dup p.R162Tfs*8 | Frame Shift Ins (INS) | VAF 32/246 reads (13%) | catalogued as rs1405120226; called by mutect2, pindel, varscan2
- FZD3 | c.1533del p.H512Mfs*8 | Frame Shift Del (DEL) | VAF 34/257 reads (13%) | catalogued as rs1563404339; called by mutect2, pindel, varscan2
- GBE1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs368555635; called by muse, mutect2, varscan2
- GBP4 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs372003146; called by muse, mutect2, varscan2
- GDF11 | c.67del p.E23Rfs*54 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | catalogued as rs1464775708; called by mutect2, pindel, varscan2
- GJA3 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 108/661 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs766975987, COSV53837050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJA3 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1425849074; called by muse, mutect2, varscan2
- GLG1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764599334, COSV52672363; called by muse, varscan2
- GPR150 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 100/657 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV101187434; called by muse, mutect2, varscan2
- GPR68 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 96/548 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773867347, COSV53176078, COSV53177210; called by muse, mutect2, varscan2
- GRIN2A | c.4126C>T p.R1376C | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs1426934537, COSV58023359, COSV58024387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRK7 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 78/572 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.545); catalogued as rs554482696; called by muse, mutect2, varscan2
- GTF2H2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs1190952489; called by muse, mutect2, varscan2
- GYS1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775388088, COSV54403155, COSV54404312; called by muse, mutect2, varscan2
- H1-7 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 92/596 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as rs755232274; called by muse, varscan2
- H2AC6 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58415140; called by muse, mutect2, varscan2
- HERC1 | c.4579G>A p.A1527T | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs748070202, COSV71249485; called by muse, mutect2, varscan2
- HEY1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV61232524; called by muse, mutect2, varscan2
- HEY2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 72/579 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100856252; called by muse, mutect2, varscan2
- HIVEP2 | c.4465C>T p.R1489C | Missense Mutation (SNP) | VAF 75/516 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs768721723; called by muse, mutect2, varscan2
- HLA-DPA1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1312481783; called by muse, mutect2, varscan2
- HNRNPAB | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 48/380 reads (13%) | catalogued as COSV57423290; called by muse, mutect2, varscan2
- HNRNPM | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 123/771 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); catalogued as COSV99725946; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 84/590 reads (14%) | catalogued as rs770632206; called by mutect2, pindel, varscan2
- HPRT1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 63/459 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1191120507; called by muse, mutect2, varscan2
- IFIH1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 85/526 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs189443152; called by muse, mutect2, varscan2
- IFIT2 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs370009481; called by muse, mutect2, varscan2
- IGF1R | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 82/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51283549; called by muse, mutect2
- IGHE | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs782328619; called by muse, mutect2, varscan2
- IL17RA | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs1012154562; called by muse, mutect2, varscan2
- IL31RA | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs140393164; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 38/295 reads (13%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- IMPDH2 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 54/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58245114; called by muse, mutect2, varscan2
- INAFM1 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 105/629 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs756117594; called by muse, mutect2, varscan2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 35/235 reads (15%) | catalogued as COSV68960008; called by mutect2, pindel, varscan2
- INTS3 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1436582387, COSV59682691; called by muse, mutect2, varscan2
- ISYNA1 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs945866048, COSV54210264; called by muse, mutect2, varscan2
- ITCH | c.869C>T p.P290L (on ENST00000262650 / NM_001257137.3; = p.P249L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs370394645; called by mutect2, varscan2
- ITGA4 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 82/477 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV52003141; called by muse, mutect2, varscan2
- IVL | c.90T>A p.H30Q | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778646992; called by muse, mutect2, varscan2
- JPH1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 77/742 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as COSV60610602; called by muse, mutect2, varscan2
- KCNA3 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63902535; called by muse, varscan2
- KCNJ15 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1306694872, COSV100154155; called by muse, mutect2, varscan2
- KCNQ3 | c.1151G>T p.R384M | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66468280; called by muse, mutect2
- KCNQ5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759489014; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 51/346 reads (15%) | catalogued as rs782541016; called by pindel, varscan2
- KDM4A | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490611372; called by muse, mutect2, varscan2
- KDM5A | c.3597dup p.G1200Rfs*7 | Frame Shift Ins (INS) | VAF 52/349 reads (15%) | catalogued as rs771545848; called by mutect2, varscan2
- KIF1B | c.2464C>T p.R822C (on ENST00000377086 / NM_001365952.1; = p.R776C on NM_015074.3) | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760896802, COSV99824082; called by muse, mutect2, varscan2
- KLC1 | c.1508_1511del p.K503Rfs*39 | Frame Shift Del (DEL) | VAF 58/426 reads (14%) | catalogued as rs753860643; called by pindel, varscan2
- KLHDC8A | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 97/574 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV65679604; called by muse, mutect2, varscan2
- KLK6 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 67/433 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs1226431504; called by muse, mutect2, varscan2
- KMT2B | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 67/490 reads (14%) | catalogued as COSV52892550; called by muse, mutect2, varscan2
- KRBA1 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs374134774; called by muse, mutect2, varscan2
- KREMEN1 | c.880G>A p.V294I (on ENST00000407188; = p.V296I on NM_032045.5) | Missense Mutation (SNP) | VAF 60/417 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs1468248789; called by muse, mutect2, varscan2
- KRI1 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 58/464 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs778912596; called by muse, mutect2, varscan2
- KRT6C | c.1660A>T p.T554S | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52877042; called by muse, mutect2, varscan2
- KYNU | c.758A>G p.H253R | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372144733; called by muse, mutect2, varscan2
- LAMB2 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 73/520 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1055560126; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 29/238 reads (12%) | catalogued as rs758463950; called by mutect2, varscan2
- LARP4 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 67/412 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370588459; called by muse, mutect2, varscan2
- LATS2 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 120/636 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV66878256; called by muse, mutect2, varscan2
- LCE2B | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.114); catalogued as rs747416050, COSV64227662; called by muse, varscan2
- LCE2B | c.296del p.G99Afs*16 | Frame Shift Del (DEL) | VAF 74/522 reads (14%) | catalogued as rs113915996; called by pindel, varscan2
- LCE2D | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 94/740 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.48); catalogued as rs564031315, COSV64228830; called by muse, mutect2
- LHX2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 120/645 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs567713261, COSV101010037; called by muse, varscan2
- LHX9 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs772729961; called by muse, mutect2, varscan2
- LIFR | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 75/409 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756414449, COSV54700169; called by muse, mutect2, varscan2
- LLGL2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144919589; called by muse, mutect2, varscan2
- LMNB2 | c.1629dup p.S544Lfs*23 | Frame Shift Ins (INS) | VAF 66/357 reads (18%) | catalogued as rs776267567; called by mutect2, varscan2
- LMTK3 | c.2175del p.A726Pfs*132 | Frame Shift Del (DEL) | VAF 43/273 reads (16%) | catalogued as rs1555901301; called by mutect2, varscan2
- LONP1 | c.296del p.G99Afs*11 | Frame Shift Del (DEL) | VAF 78/642 reads (12%) | catalogued as COSV99053765; called by mutect2, pindel, varscan2
- LRRC66 | c.1386G>C p.Q462H | Missense Mutation (SNP) | VAF 78/493 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV100603021, COSV58636766; called by muse, mutect2, varscan2
- LRRC75B | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs774605663, COSV50643430, COSV99959431; called by muse, mutect2, varscan2
- MAGEA6 | c.933G>T p.E311D | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782716070; called by muse, mutect2, varscan2
- MAN1B1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1191584687, COSV65371656; called by muse, mutect2, varscan2
- MAP2K6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99077453; called by muse, mutect2
- MAP3K6 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1462971853, COSV58871125; called by muse, mutect2, varscan2
- MARF1 | c.2720del p.K907Sfs*6 | Frame Shift Del (DEL) | VAF 41/264 reads (16%) | catalogued as rs1303520043; called by mutect2, pindel, varscan2
- MAS1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765532855; called by muse, mutect2, varscan2
- MBD3L3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 34/1225 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1002081621; called by muse, mutect2
- MC5R | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs762169294, COSV61254230; called by muse, mutect2, varscan2
- MED27 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 42/245 reads (17%) | catalogued as rs970387240; called by muse, mutect2, varscan2
- METTL14 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764382902, COSV66310476; called by muse, mutect2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 62/436 reads (14%) | catalogued as rs769987847; called by mutect2, varscan2
- MIF4GD | c.506G>A p.R169H (on ENST00000325102 / NM_001370592.1; = p.R203H on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs202019621; called by muse, mutect2, varscan2
- MKRN2 | c.975dup p.A326Sfs*3 | Frame Shift Ins (INS) | VAF 28/179 reads (16%) | catalogued as rs1377010344; called by mutect2, pindel, varscan2
- MLNR | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 104/585 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519995; called by muse, mutect2, varscan2
- MLNR | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV99519729; called by muse, mutect2, varscan2
- MMP17 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 22/804 reads (3%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1391920799, COSV62178924; called by muse, mutect2
- MMP25 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339453; called by muse, varscan2
- MPRIP | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 69/519 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.084); catalogued as rs750724857, COSV57931043; called by muse, mutect2, varscan2
- MUC12 | c.6571C>T p.R2191C (on ENST00000379442; = p.R2048C on NM_001164462.1) | Missense Mutation (SNP) | VAF 85/1878 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs1234096389; called by muse, mutect2
- MYLK | c.472del p.E158Sfs*79 | Frame Shift Del (DEL) | VAF 46/324 reads (14%) | catalogued as rs770373926; called by mutect2, varscan2
- MYO10 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs74389230, COSV72563266; called by muse, mutect2, varscan2
- MYO18B | c.6548A>C p.H2183P | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59133721; called by muse, mutect2, varscan2
- MYO1C | c.2438G>A p.R813H (on ENST00000648651 / NM_001080779.2; = p.R778H on NM_033375.5) | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs377675305; called by muse, mutect2, varscan2
- MYO9B | c.6049del p.A2017Pfs*36 | Frame Shift Del (DEL) | VAF 83/509 reads (16%) | catalogued as rs1325294870, COSV55727808; called by mutect2, pindel, varscan2
- NAALADL2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs575644923, COSV69154945; called by muse, mutect2, varscan2
- NAALADL2 | c.1554del p.N520Mfs*12 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs1478908176, COSV69154859; called by pindel, varscan2
- NFIC | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs755086095; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 76/270 reads (28%) | catalogued as rs145147241; called by mutect2, varscan2
- NISCH | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 75/592 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs372251478; called by muse, mutect2, varscan2
- NKTR | c.3856C>T p.R1286C | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs149324513; called by muse, mutect2, varscan2
- NLGN2 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV57210079; called by muse, mutect2, varscan2
- NLRP6 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1413395225; called by muse, mutect2, varscan2
- NMBR | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 68/469 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs918071854; called by muse, mutect2, varscan2
- NMRK2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140282574; called by muse, mutect2, varscan2
- NMT2 | c.1138del p.R380Gfs*9 | Frame Shift Del (DEL) | VAF 31/325 reads (10%) | catalogued as COSV65382194; called by mutect2, pindel, varscan2
- NONO | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV52136937, COSV52136980; called by muse, mutect2, varscan2
- NOS3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 101/545 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.992); catalogued as rs556096751; called by muse, mutect2, varscan2
- NOS3 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767103114; called by muse, mutect2, varscan2
- NOTCH1 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as rs771739312; called by muse, mutect2, varscan2
- NPAP1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.229); catalogued as rs778802437, COSV100274854, COSV61507542; called by muse, mutect2, varscan2
- NPC1L1 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 80/504 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs371689322, COSV56923229; called by muse, mutect2, varscan2
- NR1H4 | c.1183G>T p.E395* (on ENST00000551379 / NM_001206993.2; = p.E381* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 30/255 reads (12%) | catalogued as COSV51851718; called by muse, mutect2, varscan2
- NR1I2 | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV61977850; called by muse, mutect2, varscan2
- NUDCD1 | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53457229; called by muse, mutect2, varscan2
- OBSL1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 69/476 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs372539462; called by muse, mutect2, varscan2
- OCSTAMP | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 89/529 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.27); catalogued as rs1038135069, COSV54100163; called by muse, mutect2, varscan2
- OGFOD1 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs149156581; called by muse, mutect2, varscan2
- OGT | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV65479282; called by muse, mutect2, varscan2
- OLIG3 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 90/523 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs930803073; called by muse, mutect2, varscan2
- OPRK1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 64/582 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs200826073, COSV55570103, COSV55572545; called by muse, mutect2, varscan2
- OR13C4 | c.647del p.F216Sfs*30 | Frame Shift Del (DEL) | VAF 56/320 reads (18%) | catalogued as rs752116520, COSV52927828; called by mutect2, varscan2
- OR2T3 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 64/527 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs772068789; called by muse, mutect2, varscan2
- OR4A47 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV71444889; called by muse, mutect2, varscan2
- OR56A1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 84/532 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs749099221; called by muse, mutect2, varscan2
- OR8K3 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 71/440 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV57131018; called by muse, mutect2, varscan2
- OSBPL7 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 55/395 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs202223969; called by muse, mutect2, varscan2
- PABPC1 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 49/456 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs763908705, COSV59402591; called by mutect2, varscan2
- PAPLN | c.3152G>A p.R1051Q (on ENST00000554301; = p.R1024Q on NM_173462.4) | Missense Mutation (SNP) | VAF 68/481 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs138835922, COSV53722238; called by muse, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 50/384 reads (13%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PARP10 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 80/796 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100477798; called by muse, mutect2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 73/445 reads (16%) | catalogued as rs770881706; called by mutect2, varscan2
- PCARE | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 71/483 reads (15%) | catalogued as rs772325487, COSV100527437; called by muse, mutect2, varscan2
- PCDH12 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs775992998, COSV99192020; called by muse, mutect2, varscan2
- PCDH8 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 20/636 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV100131517; called by muse, mutect2
- PCDHA3 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 138/812 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.223); catalogued as rs781849256, COSV100793292; called by muse, mutect2, varscan2
- PCDHA5 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs781965258, COSV100972072; called by muse, mutect2, varscan2
- PCDHB11 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 108/760 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs782536109, COSV61309676; called by muse, mutect2, varscan2
- PCDHB3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50564990; called by muse, mutect2, varscan2
- PCDHB8 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 124/914 reads (14%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.017); catalogued as rs782043465; called by muse, varscan2
- PCDHGA3 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 91/774 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs760333566, COSV53939669; called by muse, varscan2
- PCLO | c.3719del p.K1240Sfs*78 | Frame Shift Del (DEL) | VAF 45/403 reads (11%) | catalogued as COSV61638231; called by mutect2, pindel, varscan2
- PCOLCE | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 72/538 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as rs772631901; called by muse, mutect2, varscan2
- PDLIM1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.621); catalogued as rs201496907; called by muse, mutect2, varscan2
- PDLIM4 | c.507C>T p.S169= | Splice Region (SNP) | VAF 47/334 reads (14%) | catalogued as rs765576278; called by muse, mutect2, varscan2
- PDPK1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 46/358 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1043839627; called by muse, mutect2, varscan2
- PDZD2 | c.4158_4160del p.S1387del | In Frame Del (DEL) | VAF 77/457 reads (17%) | catalogued as rs747785159; called by mutect2, pindel, varscan2
- PEG3 | c.2219C>A p.P740H | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55639517; called by muse, mutect2, varscan2
- PGGHG | c.513del p.P172Hfs*16 | Frame Shift Del (DEL) | VAF 68/471 reads (14%) | catalogued as rs774965357; called by mutect2, pindel, varscan2
- PGLYRP3 | c.338_340del p.N113del | In Frame Del (DEL) | VAF 44/316 reads (14%) | catalogued as rs753119157; called by pindel, varscan2
- PGM1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1453920894, COSV64301276; called by muse, varscan2
- PGR | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99679417; called by muse, mutect2, varscan2
- PHF20L1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99622280; called by muse, mutect2, varscan2
- PHF21B | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 93/618 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs765229099, COSV100503704; called by muse, mutect2, varscan2
- PIF1 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 67/482 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465615384; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 32/223 reads (14%) | catalogued as rs756552559; called by mutect2, varscan2
- PIK3R1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 63/502 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.977); catalogued as rs1402146204; called by muse, mutect2, varscan2
- PKD1L3 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs948161268, COSV100626237; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 24/219 reads (11%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEC | c.4657C>T p.R1553C (on ENST00000322810 / NM_201380.4; = p.R1443C on NM_000445.5) | Missense Mutation (SNP) | VAF 214/883 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs782780429; called by muse, mutect2, varscan2
- PLEKHA1 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64569544; called by muse, mutect2, varscan2
- PLEKHD1 | c.1494del p.S499Rfs*97 | Frame Shift Del (DEL) | VAF 48/438 reads (11%) | catalogued as COSV59448093; called by mutect2, varscan2
- PLIN2 | c.1105A>G p.S369G | Missense Mutation (SNP) | VAF 73/454 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs542037971; called by muse, mutect2, varscan2
- PNPLA6 | c.1984C>T p.R662C (on ENST00000414982 / NM_001166111.2; = p.R614C on NM_006702.5) | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs754305235; called by muse, mutect2, varscan2
- POLE | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs373468985, COSV57677387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLG2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 73/447 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV56749353; called by muse, mutect2, varscan2
- POLQ | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV51756190; called by muse, mutect2, varscan2
- POSTN | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 26/242 reads (11%) | catalogued as rs1038159113; called by muse, mutect2
- PPFIA2 | c.622_624del p.E208del | In Frame Del (DEL) | VAF 32/233 reads (14%) | catalogued as rs1402226175; called by pindel, varscan2
- PPP1R3B | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 69/424 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767303737; called by muse, mutect2, varscan2
- PPP3CA | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs765118167, COSV59926271; called by muse, mutect2, varscan2
- PPP4R1 | c.340G>A p.A114T (on ENST00000400556 / NM_001042388.3; = p.A97T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as rs1002589381, COSV53281445; called by muse, mutect2, varscan2
- PRAM1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545511903; called by muse, mutect2, varscan2
- PRG3 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs764867230; called by muse, mutect2, varscan2
- PRORP | c.1413dup p.A472Cfs*2 | Frame Shift Ins (INS) | VAF 34/280 reads (12%) | catalogued as rs766680749; called by mutect2, varscan2
- PROS1 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67776121; called by muse, mutect2, varscan2
- PRR23B | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 62/564 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as rs376706999, COSV61494856; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 16/148 reads (11%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSAPL1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 77/503 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs201099591; called by muse, mutect2, varscan2
- PSG2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs149747966; called by muse, mutect2, varscan2
- PTPN23 | c.881_882del p.V294Afs*28 | Frame Shift Del (DEL) | VAF 54/448 reads (12%) | catalogued as rs778812512; called by pindel, varscan2
- R3HCC1 | c.1406_1409del p.K469Sfs*? (on ENST00000411463; = p.K429Sfs*57 on NM_001136108.3) | Frame Shift Del (DEL) | VAF 54/362 reads (15%) | catalogued as rs750934485; called by pindel, varscan2
- RAB11FIP5 | c.1956del p.K653Nfs*107 | Frame Shift Del (DEL) | VAF 61/384 reads (16%) | catalogued as COSV99241950; called by mutect2, pindel, varscan2
- RAPGEF6 | c.1918del p.S640Vfs*59 | Frame Shift Del (DEL) | VAF 104/330 reads (32%) | catalogued as rs752725730; called by mutect2, varscan2
- RASGEF1B | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.37); catalogued as rs779067897; called by muse, mutect2, varscan2
- RASIP1 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 75/435 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs774939039; called by muse, mutect2, varscan2
- RASSF5 | c.114del p.D39Tfs*127 | Frame Shift Del (DEL) | VAF 77/550 reads (14%) | catalogued as rs1344667401; called by mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/324 reads (19%) | catalogued as rs749563266; called by mutect2, varscan2
- RBM6 | c.2502dup p.P835Tfs*9 | Frame Shift Ins (INS) | VAF 54/302 reads (18%) | catalogued as rs775573264; called by mutect2, varscan2
- REV3L | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62614958; called by muse, mutect2, varscan2
- RFNG | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 77/384 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.532); catalogued as rs1239545635, COSV57647912; called by muse, mutect2, varscan2
- RGS12 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1415813040; called by muse, mutect2, varscan2
- RGS22 | c.3698dup p.L1234Vfs*12 | Frame Shift Ins (INS) | VAF 44/288 reads (15%) | catalogued as rs1424445251; called by mutect2, varscan2
- RGS3 | c.2911G>A p.A971T (on ENST00000350696 / NM_001282923.2; = p.A690T on NM_130795.4) | Missense Mutation (SNP) | VAF 81/510 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs145465954, COSV100637120; called by muse, mutect2, varscan2
- RHBDF2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 90/663 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs755689331; called by muse, mutect2, varscan2
- RHCG | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs543708260, COSV99174052; called by muse, mutect2, varscan2
- RIMKLA | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs755204576, COSV68909655; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 49/264 reads (19%) | catalogued as rs757038390; called by mutect2, varscan2
- RNPEP | c.930del p.C311Afs*3 | Frame Shift Del (DEL) | VAF 62/461 reads (13%) | catalogued as rs1489424290; called by mutect2, pindel, varscan2
- RPS6KA4 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs779918376, COSV99589746, COSV99590341; called by muse, mutect2, varscan2
- RRM2B | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 68/505 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52568522; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 63/306 reads (21%) | catalogued as rs747510098; called by mutect2, varscan2
- RTP5 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 86/642 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.02); catalogued as rs1295514294; called by muse, mutect2, varscan2
- RYR3 | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV66777902; called by muse, mutect2, varscan2
- RYR3 | c.6764C>T p.A2255V | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs796687835, COSV63109638; called by muse, mutect2, varscan2
- SBF1 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 116/624 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs755768063, COSV100818056; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 46/290 reads (16%) | catalogued as rs765867975; called by mutect2, varscan2
- SCARF1 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 98/661 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53959801; called by muse, mutect2, varscan2
- SCART1 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 99/668 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1298838703; called by muse, mutect2, varscan2
- SCGN | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV58545332, COSV58545636; called by muse, mutect2, varscan2
- SDC1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745498874, COSV54339097; called by muse, mutect2, varscan2
- SDK2 | c.4894G>A p.V1632I | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs781724733; called by muse, mutect2, varscan2
- SDK2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs559453244; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 39/278 reads (14%) | catalogued as rs750651342; called by mutect2, varscan2
- SEPTIN5 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV63530868; called by muse, mutect2, varscan2
- SETMAR | c.1409dup p.N470Kfs*5 | Frame Shift Ins (INS) | VAF 47/328 reads (14%) | catalogued as rs866854143; called by mutect2, varscan2
- SFSWAP | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322718182, COSV55520068; called by muse, mutect2, varscan2
- SGCZ | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV66001930; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 40/328 reads (12%) | catalogued as rs774210627; called by mutect2, pindel, varscan2
- SIPA1L1 | c.5057C>T p.A1686V | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100665271; called by muse, mutect2, varscan2
- SKIV2L | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138507648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKIV2L | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 97/659 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762204789; called by muse, mutect2, varscan2
- SLC25A47 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 82/518 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs978289874, COSV64161587; called by muse, mutect2, varscan2
- SLC26A7 | c.1287del p.K429Nfs*37 | Frame Shift Del (DEL) | VAF 36/288 reads (13%) | catalogued as COSV99403944; called by mutect2, pindel, varscan2
- SLC34A2 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 63/579 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs775481758; called by muse, mutect2, varscan2
- SLC35F4 | c.690del p.K230Nfs*14 (on ENST00000339762 / NM_001352015.2; = p.K194Nfs*14 on NM_001206920.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/177 reads (12%) | catalogued as rs1182692783; called by mutect2, pindel, varscan2
- SLC46A2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 82/458 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371414131; called by muse, varscan2
- SLC4A4 | c.1135G>A p.V379I (on ENST00000264485 / NM_001098484.3; = p.V335I on NM_003759.4) | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs781031046; called by muse, mutect2, varscan2
- SLC5A3 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 60/402 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs144212752; called by muse, mutect2, varscan2
- SLC9A3R2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs761961644; called by muse, mutect2, varscan2
- SLITRK4 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs997536820, COSV100567547, COSV62023284; called by muse, mutect2, varscan2
- SLN | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs375547331; called by muse, mutect2, varscan2
- SLX4 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 76/522 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs148428054; called by muse, mutect2, varscan2
- SMC1A | c.1142_1144del p.E381del | In Frame Del (DEL) | VAF 56/442 reads (13%) | catalogued as rs797045991; called by pindel, varscan2
- SMG8 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 79/429 reads (18%) | catalogued as COSV56287002; called by muse, mutect2, varscan2
- SMTNL1 | c.205del p.E69Kfs*5 | Frame Shift Del (DEL) | VAF 89/596 reads (15%) | catalogued as rs1258300994; called by mutect2, pindel, varscan2
- SNIP1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 47/405 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370698062; called by muse, mutect2, varscan2
- SNRPA | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 61/453 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as rs768970890; called by muse, mutect2, varscan2
- SOAT1 | c.1146dup p.A383Cfs*12 | Frame Shift Ins (INS) | VAF 37/262 reads (14%) | catalogued as rs1215692421; called by mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 44/344 reads (13%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOX1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); catalogued as rs1465709458; called by muse, mutect2, varscan2
- SOX18 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1161173722; called by muse, mutect2
- SPATA31A1 | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 76/924 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1320560402; called by muse, mutect2
- SPEM2 | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 97/600 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs113604978, COSV60366859; called by muse, mutect2, varscan2
- SPTB | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179544605; called by muse, mutect2, varscan2
- SPTBN5 | c.7174T>C p.C2392R | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs762252387; called by muse, mutect2, varscan2
- SRGAP3 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 75/531 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs776049201, COSV64538342; called by muse, mutect2, varscan2
- ST14 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767694949; called by muse, mutect2, varscan2
- STARD13 | c.2383G>A p.D795N (on ENST00000336934 / NM_001243476.3; = p.D677N on NM_052851.3) | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs144923151; called by muse, mutect2, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 53/378 reads (14%) | catalogued as rs762120842, COSV51992441; called by mutect2, pindel, varscan2
- STUB1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 79/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50198745; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SZRD1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 71/521 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1266298866; called by muse, mutect2, varscan2
- TAF9 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs374084798; called by muse, varscan2
- TAS1R3 | c.1544A>G p.H515R | Missense Mutation (SNP) | VAF 67/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776752562; called by muse, mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TBX21 | c.182del p.G61Afs*77 | Frame Shift Del (DEL) | VAF 81/555 reads (15%) | catalogued as rs1555625645; called by mutect2, pindel, varscan2
- TCF20 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 68/521 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs750743110; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 44/358 reads (12%) | catalogued as COSV61906772; called by mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 42/235 reads (18%) | catalogued as rs745872748; called by mutect2, varscan2
- TECTA | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 89/505 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs137951168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM2 | c.850G>A p.A284T (on ENST00000518659 / NM_001122679.2; = p.A93T on NM_001080428.3) | Missense Mutation (SNP) | VAF 73/529 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.933); catalogued as rs778401983; called by muse, mutect2, varscan2
- TENT2 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs772556872; called by muse, mutect2, varscan2
- TEX2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs768286288; called by muse, mutect2, varscan2
- TGFBR2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 64/478 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs769750420; called by muse, varscan2
- THBS2 | c.3101G>A p.S1034N | Missense Mutation (SNP) | VAF 52/497 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as rs777940757; called by muse, mutect2, varscan2
- THEMIS2 | c.1652dup p.P552Tfs*5 | Frame Shift Ins (INS) | VAF 54/383 reads (14%) | catalogued as rs750840849; called by mutect2, varscan2
- TLR3 | c.38dup p.L14Pfs*18 | Frame Shift Ins (INS) | VAF 56/338 reads (17%) | catalogued as rs757908313; called by mutect2, varscan2
- TMEM131L | c.4319A>G p.H1440R | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs1409986689; called by muse, mutect2
- TMEM132C | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 56/449 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs780371502; called by muse, mutect2, varscan2
- TMEM268 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs996118158, COSV99938792; called by muse, mutect2, varscan2
- TMEM53 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 90/513 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776174614, COSV62406557, COSV62408279; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 138/406 reads (34%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM88B | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 93/634 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302771591; called by muse, mutect2, varscan2
- TMPRSS11D | c.739_741del p.T247del | In Frame Del (DEL) | VAF 26/206 reads (13%) | catalogued as rs1266225665; called by pindel, varscan2
- TMPRSS15 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 48/439 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV99517573; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs965706851; called by muse, mutect2, varscan2
- TNS3 | c.3739C>T p.R1247W | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757609951, COSV60796182; called by muse, mutect2, varscan2
- TNXB | c.4705G>A p.D1569N (on ENST00000647633; = p.D1322N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1280340355, COSV100925874; called by muse, mutect2, varscan2
- TONSL | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 115/508 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755575416; called by muse, mutect2, varscan2
- TOR1B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs774873503; called by muse, mutect2, varscan2
- TPM3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 55/395 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs761891060, COSV55135635; called by muse, mutect2, varscan2
- TPO | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 94/572 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as rs1430829526; called by muse, varscan2
- TPTE2 | c.293C>T p.T98I (on ENST00000400230 / NM_199254.2; = p.T61I on NM_130785.3) | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1165821523; called by muse, mutect2, varscan2
- TRIM50 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 90/538 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs151103619; called by muse, mutect2, varscan2
- TRIM62 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775619590, COSV99357926; called by muse, mutect2, varscan2
- TRIM66 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1437917471, COSV55125379; called by muse, mutect2, varscan2
- TRIP11 | c.4753C>T p.R1585C | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs777125011, COSV50932133; called by muse, mutect2, varscan2
- TRPC6 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs199503731; called by muse, mutect2, varscan2
- TRPM5 | c.1788C>G p.F596L | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.406); catalogued as COSV99330212; called by muse, mutect2, varscan2
- TSC1 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs914628341, COSV53765594; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 88/490 reads (18%) | catalogued as rs1193207010; called by mutect2, varscan2
- TTC3 | c.5611C>T p.R1871* | Nonsense Mutation (SNP) | VAF 44/224 reads (20%) | catalogued as rs1479152815; called by muse, varscan2
- TTC6 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV101606734; called by muse, mutect2, varscan2
- TTLL1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 81/448 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs941132746, COSV99840293; called by muse, mutect2, varscan2
- TTN | c.53302C>T p.R17768C (on ENST00000591111; = p.R10344C on NM_003319.4) | Missense Mutation (SNP) | VAF 71/419 reads (17%) | PolyPhen possibly damaging (0.87); catalogued as rs553606996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP1L | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 58/403 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs972027429, COSV99072870; called by muse, mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 60/449 reads (13%) | catalogued as rs1243652090; called by mutect2, pindel, varscan2
- ULK3 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs941009587; called by muse, mutect2, varscan2
- UPF1 | c.2893C>T p.R965W (on ENST00000599848 / NM_001297549.2; = p.R954W on NM_002911.4) | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.821); catalogued as rs750432625; called by muse, mutect2, varscan2
- UPF2 | c.3099A>T p.E1033D | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1367060563, COSV62658267; called by muse, mutect2, varscan2
- USF1 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs777990631; called by muse, mutect2, varscan2
- USP44 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs144639311; called by muse, mutect2, varscan2
- VAC14 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 46/417 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769516806; called by muse, mutect2, varscan2
- VASH1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 85/616 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1221271711; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 40/264 reads (15%) | catalogued as rs748321397; called by mutect2, varscan2
- VILL | c.815dup p.L273Tfs*30 | Frame Shift Ins (INS) | VAF 62/438 reads (14%) | catalogued as rs751305489; called by mutect2, varscan2
- VIM | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 94/598 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.189); catalogued as rs748519640; called by muse, mutect2, varscan2
- VPS37D | c.748del p.H250Tfs*75 | Frame Shift Del (DEL) | VAF 23/171 reads (13%) | catalogued as rs1563540888; called by mutect2, pindel, varscan2
- VWA1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 104/660 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1347964556; called by muse, mutect2, varscan2
- WDFY3 | c.5723G>A p.R1908H | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1217913024, COSV104399957; called by muse, mutect2, varscan2
- WDR13 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 62/440 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1326275689, COSV99489098; called by muse, mutect2, varscan2
- WDR33 | c.3914G>A p.R1305Q | Missense Mutation (SNP) | VAF 84/507 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs766276994, COSV59249179; called by muse, mutect2, varscan2
- WDR7 | c.3146C>T p.A1049V | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1256507873; called by muse, mutect2, varscan2
- WDR97 | c.921G>T p.M307I | Missense Mutation (SNP) | VAF 130/570 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as rs185229941; called by muse, mutect2, varscan2
- WSCD1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs773447795; called by muse, mutect2, varscan2
- WT1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 111/567 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs886048229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWP2 | c.2419G>A p.G807R | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763322178, COSV100598518, COSV63125175; called by muse, mutect2, varscan2
- XIRP2 | c.2527A>G p.R843G (on ENST00000628543; = p.R1018G on NM_152381.6) | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54683341; called by muse, mutect2, varscan2
- XKR4 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1468126935; called by muse, varscan2
- XPO6 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV100484782; called by muse, mutect2, varscan2
- XYLT2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 116/622 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1482492836, COSV50017930, COSV99191285; called by muse, mutect2
- ZBTB22 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 125/821 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs925467606; called by muse, mutect2, varscan2
- ZBTB7B | c.301G>A p.A101T (on ENST00000292176; = p.A135T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/520 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200691018; called by muse, mutect2, varscan2
- ZC3H10 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1252455397, COSV57769760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3H6 | c.588del p.K196Nfs*4 | Frame Shift Del (DEL) | VAF 37/254 reads (15%) | catalogued as COSV59671010; called by mutect2, pindel, varscan2
- ZCCHC12 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.23); catalogued as COSV100038537; called by muse, mutect2, varscan2
- ZCCHC8 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs538195616; called by muse, mutect2, varscan2
- ZDHHC3 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as rs760297347, COSV99943683; called by muse, mutect2, varscan2
- ZFAT | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 65/643 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs374372896, COSV64735305; called by muse, mutect2, varscan2
- ZFHX4 | c.7654C>A p.L2552M | Missense Mutation (SNP) | VAF 82/604 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as rs1170669163; called by muse, mutect2, varscan2
- ZNF175 | c.1118del p.F373Sfs*90 | Frame Shift Del (DEL) | VAF 66/423 reads (16%) | catalogued as rs1568577121; called by mutect2, pindel, varscan2
- ZNF202 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1431862921; called by muse, mutect2, varscan2
- ZNF214 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs191766009, COSV99547366; called by muse, mutect2, varscan2
- ZNF225 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs775610091, COSV99489594; called by muse, mutect2, varscan2
- ZNF34 | c.664del p.T222Qfs*15 | Frame Shift Del (DEL) | VAF 39/317 reads (12%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF414 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 93/592 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1290943713; called by muse, mutect2, varscan2
- ZNF425 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 67/438 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.172); catalogued as rs199919803; called by muse, mutect2, varscan2
- ZNF71 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs763304877; called by muse, mutect2, varscan2
- ZNF764 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 92/600 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746773274; called by muse, mutect2, varscan2
- ZNF782 | c.1577G>C p.R526T | Missense Mutation (SNP) | VAF 73/586 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56651047; called by muse, mutect2, varscan2
- ZNF837 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 101/566 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758902809; called by muse, mutect2, varscan2
- A1BG | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 113/551 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AARS2 | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 76/483 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- ABCA8 | c.4732del p.Q1578Rfs*37 | Frame Shift Del (DEL) | VAF 43/281 reads (15%) | called by mutect2, pindel, varscan2
- ABCC5 | c.1481dup p.N494Kfs*44 | Frame Shift Ins (INS) | VAF 59/394 reads (15%) | called by mutect2, pindel, varscan2
- ABCC9 | c.4212A>C p.R1404S | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ABHD16A | c.961del p.V321Cfs*22 | Frame Shift Del (DEL) | VAF 43/281 reads (15%) | called by mutect2, pindel, varscan2
- AC073111.3 | c.437del p.H146Pfs*54 | Frame Shift Del (DEL) | VAF 93/642 reads (14%) | called by mutect2, pindel, varscan2
- ACKR2 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ADAMTS1 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 55/402 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.4136dup p.D1380Gfs*7 | Frame Shift Ins (INS) | VAF 56/366 reads (15%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 82/727 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, varscan2
- ADGRG4 | c.4865del p.N1622Tfs*12 | Frame Shift Del (DEL) | VAF 62/473 reads (13%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.498del p.E167Sfs*62 | Frame Shift Del (DEL) | VAF 51/312 reads (16%) | called by mutect2, pindel, varscan2
- AL096814.1 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ALDH1L1 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 65/417 reads (16%) | called by muse, mutect2, varscan2
- AMIGO3 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 76/455 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANKLE1 | c.353G>A p.R118H (on ENST00000394458; = p.R64H on NM_152363.6) | Missense Mutation (SNP) | VAF 67/425 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, varscan2
- ANKRD13B | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 86/529 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD33 | c.533del p.G178Vfs*7 (on ENST00000340970 / NM_001304459.2; = p.G303Vfs*7 on NM_182608.4) | Frame Shift Del (DEL) | VAF 78/566 reads (14%) | called by mutect2, varscan2
- ANKRD33B | c.135T>A p.S45R | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO8 | c.3493del p.R1165Afs*154 | Frame Shift Del (DEL) | VAF 28/251 reads (11%) | called by mutect2, pindel, varscan2
- ARC | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 87/753 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 61/317 reads (19%) | called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.626dup p.N209Kfs*2 | Frame Shift Ins (INS) | VAF 58/429 reads (14%) | called by mutect2, varscan2
- ARPP21 | c.1862del p.P621Lfs*72 | Frame Shift Del (DEL) | VAF 55/420 reads (13%) | called by mutect2, pindel, varscan2
- ATAD1 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ATP11C | c.2943dup p.Q982Sfs*103 | Frame Shift Ins (INS) | VAF 43/339 reads (13%) | called by pindel, varscan2
- ATP1A3 | c.1267G>A p.A423T (on ENST00000545399 / NM_001256214.2; = p.A410T on NM_152296.5) | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ATP2A1 | c.1930dup p.E644Gfs*22 | Frame Shift Ins (INS) | VAF 84/517 reads (16%) | called by mutect2, pindel, varscan2
- ATP6V0A2 | c.1344del p.F448Lfs*9 | Frame Shift Del (DEL) | VAF 52/282 reads (18%) | called by mutect2, pindel, varscan2
- ATP8A2 | c.1610del p.K537Sfs*16 | Frame Shift Del (DEL) | VAF 38/298 reads (13%) | called by mutect2, pindel, varscan2
- AVPR2 | c.910+4G>A | Splice Region (SNP) | VAF 67/451 reads (15%) | called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 154/560 reads (28%) | called by pindel, varscan2
- B3GNT3 | c.745del p.W249Gfs*10 | Frame Shift Del (DEL) | VAF 62/463 reads (13%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.1768G>T p.G590* | Nonsense Mutation (SNP) | VAF 49/343 reads (14%) | called by muse, mutect2, varscan2
- BCL9 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BCOR | c.1586del p.N529Tfs*60 | Frame Shift Del (DEL) | VAF 101/631 reads (16%) | called by mutect2, pindel, varscan2
- BICRAL | c.3181G>T p.G1061C | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- BIRC6 | c.13509del p.K4503Nfs*11 | Frame Shift Del (DEL) | VAF 36/210 reads (17%) | called by mutect2, varscan2
- BMP6 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 63/492 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BOD1L1 | c.2692C>T p.R898* | Nonsense Mutation (SNP) | VAF 70/428 reads (16%) | called by muse, mutect2, varscan2
- BRSK2 | c.1063del p.R355Gfs*4 | Frame Shift Del (DEL) | VAF 47/334 reads (14%) | called by mutect2, varscan2
- BTBD2 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BTNL9 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C17orf113 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- C18orf63 | c.1018del p.M340Cfs*6 | Frame Shift Del (DEL) | VAF 42/379 reads (11%) | called by mutect2, pindel, varscan2
- CA3 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMK2D | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPN1 | c.188del p.P63Rfs*113 | Frame Shift Del (DEL) | VAF 65/515 reads (13%) | called by mutect2, varscan2
- CAPN1 | c.1438C>A p.L480M | Missense Mutation (SNP) | VAF 78/530 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN6 | c.1782dup p.Q595Afs*7 | Frame Shift Ins (INS) | VAF 64/418 reads (15%) | called by mutect2, pindel, varscan2
- CASKIN2 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBWD5 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CCDC137 | c.486dup p.A163Sfs*12 | Frame Shift Ins (INS) | VAF 28/218 reads (13%) | called by mutect2, pindel, varscan2
- CCDC183 | c.430del p.L144Cfs*16 | Frame Shift Del (DEL) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- CCDC22 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 87/626 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CCDC34 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CCDC63 | c.672G>A p.R224= | Splice Region (SNP) | VAF 57/275 reads (21%) | called by muse, mutect2, varscan2
- CCNT2 | c.1909dup p.S637Kfs*7 (on ENST00000264157 / NM_058241.3; = p.S637Kfs*16 on NM_001241.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 57/432 reads (13%) | called by mutect2, pindel, varscan2
- CCP110 | c.1926G>T p.E642D | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CD5L | c.255del p.E86Sfs*68 | Frame Shift Del (DEL) | VAF 75/442 reads (17%) | called by mutect2, pindel, varscan2
- CD93 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 75/480 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC25A | c.113del p.G38Dfs*8 | Frame Shift Del (DEL) | VAF 85/590 reads (14%) | called by pindel, varscan2
- CDK5R2 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 71/485 reads (15%) | called by muse, mutect2, varscan2
- CDK8 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR1 | c.7944dup p.G2649Rfs*98 | Frame Shift Ins (INS) | VAF 44/263 reads (17%) | called by mutect2, pindel, varscan2
- CEP295 | c.3865T>C p.S1289P | Missense Mutation (SNP) | VAF 59/464 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHIC1 | c.362A>C p.E121A | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCA1 | c.2739A>G p.I913M | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CLEC4M | c.1137T>A p.N379K | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CLHC1 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2
- CMIP | c.763del p.R255Gfs*29 (on ENST00000537098 / NM_198390.2; = p.R161Gfs*29 on NM_030629.3) | Frame Shift Del (DEL) | VAF 67/530 reads (13%) | called by mutect2, pindel, varscan2
- CNOT4 | c.326del p.N109Tfs*6 | Frame Shift Del (DEL) | VAF 63/388 reads (16%) | called by mutect2, pindel, varscan2
- CNTN6 | c.1252_1253del p.K418Vfs*33 | Frame Shift Del (DEL) | VAF 40/315 reads (13%) | called by pindel, varscan2
- CNTRL | c.5652del p.K1884Nfs*60 | Frame Shift Del (DEL) | VAF 37/251 reads (15%) | called by mutect2, pindel, varscan2
- COASY | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 96/537 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- COBL | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- COL18A1 | c.4084C>A p.P1362T (on ENST00000359759 / NM_130444.3; = p.P1127T on NM_030582.4) | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, varscan2
- CPA6 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CTNNA2 | c.2551A>G p.S851G | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, varscan2
- CTNND1 | c.451del p.R151Gfs*84 | Frame Shift Del (DEL) | VAF 58/402 reads (14%) | called by mutect2, pindel, varscan2
- CUL3 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CYHR1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 61/608 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CYLC1 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 44/353 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DBF4 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DCAF13 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 35/278 reads (13%) | called by muse, mutect2, varscan2
- DCN | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DDX20 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX43 | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DENND4B | c.926del p.G309Afs*64 | Frame Shift Del (DEL) | VAF 94/722 reads (13%) | called by mutect2, pindel, varscan2
- DENND4C | c.966del p.F322Lfs*55 | Frame Shift Del (DEL) | VAF 43/270 reads (16%) | called by mutect2, pindel, varscan2
- DHRS3 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DIP2A | c.3002A>G p.H1001R | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DIP2B | c.3535_3536del p.L1179Vfs*9 | Frame Shift Del (DEL) | VAF 43/279 reads (15%) | called by pindel, varscan2
- DNAAF5 | c.1931+1dup | Frame Shift Ins (INS) | VAF 38/296 reads (13%) | called by mutect2, pindel, varscan2
- DNAH11 | c.5491T>C p.S1831P | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DNAH11 | c.12146dup p.T4050Nfs*15 | Frame Shift Ins (INS) | VAF 40/369 reads (11%) | called by mutect2, pindel, varscan2
- DNAH2 | c.3908T>C p.I1303T | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNAH9 | c.12494T>A p.I4165N | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DNAJB4 | c.908del p.N303Ifs*9 | Frame Shift Del (DEL) | VAF 45/460 reads (10%) | called by mutect2, pindel, varscan2
- DOCK4 | c.4714C>T p.L1572F | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD4 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 61/407 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKNMT | c.829A>G p.T277A (on ENST00000361735 / NM_015935.5; = p.T191A on NM_014955.3) | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ELFN1 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 88/535 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ELOVL4 | c.549del p.F183Lfs*5 | Frame Shift Del (DEL) | VAF 25/200 reads (13%) | called by mutect2, pindel, varscan2
- ENTPD3 | c.1009_1011del p.K337del | In Frame Del (DEL) | VAF 50/472 reads (11%) | called by mutect2, pindel
- EPHA6 | c.2383A>G p.K795E (on ENST00000389672 / NM_001080448.3; = p.K187E on NM_173655.4) | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 81/752 reads (11%) | called by mutect2, pindel, varscan2
- EYS | c.5134G>T p.G1712* | Nonsense Mutation (SNP) | VAF 41/307 reads (13%) | called by muse, mutect2, varscan2
- FAM120C | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 96/666 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, varscan2
- FAM13B | c.728del p.K243Sfs*25 | Frame Shift Del (DEL) | VAF 43/325 reads (13%) | called by mutect2, pindel, varscan2
- FAM177B | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- FAM178B | c.338del p.P113Rfs*31 | Frame Shift Del (DEL) | VAF 63/556 reads (11%) | called by mutect2, pindel, varscan2
- FAM205C | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM50B | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 70/446 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM83C | c.2171A>G p.H724R | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FANCA | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- FARS2 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- FASTKD1 | c.263del p.N88Mfs*17 | Frame Shift Del (DEL) | VAF 62/412 reads (15%) | called by mutect2, pindel, varscan2
- FCHO1 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 67/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD1 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 112/720 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FIZ1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 92/518 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- FLT3LG | c.661-1G>T p.X221_splice | Splice Site (SNP) | VAF 69/522 reads (13%) | called by muse, mutect2, varscan2
- FNBP1 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FOXO1 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- FRAS1 | c.8537C>T p.A2846V | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FRRS1 | c.370del p.T124Qfs*20 | Frame Shift Del (DEL) | VAF 32/221 reads (14%) | called by mutect2, pindel, varscan2
- FUT6 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 91/604 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 57/256 reads (22%) | called by mutect2, varscan2
- GAL3ST3 | c.757delinsGG p.R253Gfs*116 | Frame Shift Ins (INS) | VAF 80/513 reads (16%) | called by pindel, varscan2*
- GALNT18 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GDF5 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GGA2 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GLE1 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLYATL2 | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GMPR | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GOLGA6L2 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- GPRC6A | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIP1 | c.3329del p.F1110Sfs*36 (on ENST00000359742 / NM_001379345.1; = p.F1058Sfs*36 on NM_021150.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 64/397 reads (16%) | called by mutect2, pindel, varscan2
- GSDME | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- H2BC17 | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- HBQ1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 67/403 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- HDGFL2 | c.1759del p.Q587Rfs*16 | Frame Shift Del (DEL) | VAF 49/421 reads (12%) | called by mutect2, pindel, varscan2
- HEATR5A | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELLS | c.1970del p.N657Tfs*15 | Frame Shift Del (DEL) | VAF 32/224 reads (14%) | called by mutect2, pindel, varscan2
- HES5 | c.422del p.P141Rfs*114 | Frame Shift Del (DEL) | VAF 17/176 reads (10%) | called by pindel, varscan2
- HLA-F | c.392_394del p.L131del | In Frame Del (DEL) | VAF 64/434 reads (15%) | called by pindel, varscan2
- HS3ST4 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- HSF5 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 26/700 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.088); called by muse, mutect2
- HSPA14 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- HUWE1 | c.10829G>A p.R3610Q | Missense Mutation (SNP) | VAF 87/547 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- IBTK | c.1754A>G p.H585R | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IER5L | c.508del p.H170Tfs*90 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
- IER5L | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- IGKV3D-11 | c.329A>C p.Q110P | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IL17RA | c.2300dup p.C768Lfs*3 | Frame Shift Ins (INS) | VAF 79/644 reads (12%) | called by mutect2, pindel, varscan2
- INO80D | c.1638dup p.H547Tfs*51 | Frame Shift Ins (INS) | VAF 65/504 reads (13%) | called by mutect2, pindel, varscan2
- INTS1 | c.2933G>A p.R978H | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS1 | c.2731_2732del p.C911Rfs*53 | Frame Shift Del (DEL) | VAF 59/440 reads (13%) | called by pindel, varscan2
- ITPRIP | c.436del p.Y146Mfs*30 | Frame Shift Del (DEL) | VAF 69/542 reads (13%) | called by mutect2, pindel, varscan2
- JADE2 | c.1982C>A p.A661D | Missense Mutation (SNP) | VAF 84/590 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- JCAD | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 80/548 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, varscan2
- JMJD1C | c.4112dup p.N1371Kfs*23 | Frame Shift Ins (INS) | VAF 56/370 reads (15%) | called by mutect2, varscan2
- KCNA3 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KCNA5 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KDM4E | c.266del p.K89Rfs*5 | Frame Shift Del (DEL) | VAF 64/418 reads (15%) | called by mutect2, varscan2
- KIAA1109 | c.13424C>G p.A4475G | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- KIAA1328 | c.853A>C p.M285L | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIRREL1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 73/492 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KLF3 | c.452A>C p.Q151P | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KLF9 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 64/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRI1 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 59/444 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KRI1 | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 59/445 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT80 | c.622del p.S208Afs*8 | Frame Shift Del (DEL) | VAF 50/342 reads (15%) | called by mutect2, pindel, varscan2
- LAMA5 | c.5285T>C p.L1762P | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- LAMC2 | c.3491A>T p.D1164V | Missense Mutation (SNP) | VAF 74/522 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LARP4B | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 11/271 reads (4%) | called by muse, mutect2
- LDB3 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 53/379 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LDB3 | c.1293del p.S432Pfs*60 | Frame Shift Del (DEL) | VAF 36/230 reads (16%) | called by mutect2, pindel
- LILRA2 | c.1407G>T p.E469D (on ENST00000391738 / NM_001130917.3; = p.E452D on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/593 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LMNA | c.1807T>G p.S603A | Missense Mutation (SNP) | VAF 76/528 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIT3 | c.1439T>G p.L480R | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP1 | c.10129G>A p.G3377R | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRP12 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC41 | c.2033_2035del p.S678del | In Frame Del (DEL) | VAF 41/274 reads (15%) | called by mutect2, pindel, varscan2
- LRRIQ4 | c.1117T>G p.S373A | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- LYST | c.3890dup p.L1297Ffs*5 | Frame Shift Ins (INS) | VAF 28/237 reads (12%) | called by mutect2, pindel, varscan2
- MAGEA11 | c.138A>T p.E46D | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MAGEA8 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 56/536 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAMLD1 | c.2045A>G p.H682R | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAP1A | c.5468C>A p.P1823H | Missense Mutation (SNP) | VAF 59/451 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); called by mutect2, varscan2
- MAP4K3 | c.1996del p.I666Sfs*13 | Frame Shift Del (DEL) | VAF 30/319 reads (9%) | called by mutect2, pindel
- MARCKS | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, varscan2
- MATN4 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 60/395 reads (15%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2L2 | c.753G>A p.Q251= | Splice Region (SNP) | VAF 49/259 reads (19%) | called by muse, mutect2, varscan2
- MDN1 | c.13587dup p.A4530Sfs*6 | Frame Shift Ins (INS) | VAF 49/403 reads (12%) | called by mutect2, pindel, varscan2
- MERTK | c.2039A>T p.H680L | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MEX3B | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MEX3B | c.249dup p.R84Afs*5 | Frame Shift Ins (INS) | VAF 52/370 reads (14%) | called by mutect2, pindel, varscan2
- MEX3D | c.104del p.P35Rfs*133 | Frame Shift Del (DEL) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- MFSD8 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MGAT4B | c.658del p.H220Tfs*34 | Frame Shift Del (DEL) | VAF 61/452 reads (13%) | called by mutect2, pindel, varscan2
- MIB2 | c.2762C>T p.P921L | Missense Mutation (SNP) | VAF 101/468 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICAL2 | c.5465C>T p.A1822V | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MICAL3 | c.3639del p.S1214Rfs*3 | Frame Shift Del (DEL) | VAF 62/497 reads (12%) | called by mutect2, pindel, varscan2
- MORC1 | c.264del p.K88Nfs*6 | Frame Shift Del (DEL) | VAF 36/257 reads (14%) | called by mutect2, pindel, varscan2
- MPP4 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.3103A>G p.K1035E | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- MSI1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2
- MTIF2 | c.326del p.N109Tfs*10 | Frame Shift Del (DEL) | VAF 38/261 reads (15%) | called by mutect2, pindel, varscan2
- MTRF1 | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MUC16 | c.6391C>A p.L2131I | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MXRA5 | c.7477A>G p.N2493D | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, varscan2
- MYBPH | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 66/502 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MYH13 | c.201C>G p.D67E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MYL6B | c.64_66del p.A22del | In Frame Del (DEL) | VAF 52/341 reads (15%) | called by pindel, varscan2
- MYO1G | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAP1L2 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); called by mutect2, varscan2
- NAV3 | c.560A>C p.H187P | Missense Mutation (SNP) | VAF 75/459 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- NBEAL2 | c.5973_5975del p.F1992del | In Frame Del (DEL) | VAF 66/450 reads (15%) | called by pindel, varscan2
- NCCRP1 | c.671dup p.G225Wfs*66 | Frame Shift Ins (INS) | VAF 64/481 reads (13%) | called by mutect2, pindel, varscan2
- NEFH | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 97/600 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEK5 | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NEO1 | c.1938T>A p.N646K | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- NFKBIA | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFS1 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKX1-1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 82/551 reads (15%) | SIFT tolerated, low confidence (0.25); called by muse, mutect2, varscan2
- NKX2-2 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 74/446 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.031); called by mutect2, varscan2
- NKX2-5 | c.975G>T p.*325Yext*18 | Nonstop Mutation (SNP) | VAF 37/271 reads (14%) | called by muse, mutect2, varscan2
- NLRP7 | c.2938del p.C980Afs*32 (on ENST00000340844 / NM_206828.3; = p.C1009Afs*32 on NM_139176.3) | Frame Shift Del (DEL) | VAF 47/294 reads (16%) | called by mutect2, pindel, varscan2
- NLRP7 | c.2662A>T p.T888S (on ENST00000340844 / NM_206828.3; = p.T860S on NM_139176.3) | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- NOTCH1 | c.5903C>A p.A1968D | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NOTO | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NPFFR2 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NPR3 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 74/526 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); called by muse, varscan2
500 further variants in this file (173 protein-altering or splice-affecting, 272 silent, 55 other) are not listed here.
